Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7602, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7602-01A (Primary Tumor).

Tumor: [REDACTED]
Normal: [REDACTED]
Slide: [REDACTED]

Microscopic Description:

H&E stained tissue demonstrates a moderately cellular neoplasm consisting of cells demonstrating perinuclear clearing. No necrosis is identified. No vascular proliferation is identified. The mitotic count is 0 per 20 high –power fields.

Addendum Discussion:

The sections demonstrates a minimally hypercellular glial neoplasm that diffusely infiltrates both the gray and white matter. In the gray matter, perineural satellitosis is seen. The tumor cells have round nuclei with little atypia. Most have just a small cap of eosinophilic cytoplasm without prominent fibrillary processes. The minority demonstrates well-formed perinuclear halos. No mitotic figures are seen. There is no microvascular proliferation or necrosis. Only rare MIB-1 reactive cells are present, with a labeling index of 0.1%, indicative of a minimally proliferation neoplasm.

Addendum Diagnosis:

Oligodendroglioma, WHO Grade II
MIB-1 Labeling Index= <0.1%

Source: NCI Genomic Data Commons file 4fd3f0ac-61ab-4bae-a602-42a39fb4b73d (TCGA-HT-7602.0AE8D27A-943E-48AC-8C70-C7FA3511AD2F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).